Surgical pathology report (de-identified scan), TCGA case TCGA-77-8148, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Prince Charles Hospital, specimen TCGA-77-8148-01A (Primary Tumor).

[page 1 of 2]
Histopathology Report

HISTORY

NSCLC (close to main bronchus). Left pneumonectomy.

MACROSCOPIC

Two specimens received:

1: The specimen is labelled 'left lung' and consists of a left sided pneumonectomy including upper and lower lobes measuring 265 mm SI x 170 mm AP x 48 mm ML. The left main bronchus extends 22 mm from the hilar margin. This bronchus is macroscopically uninvolved by tumour for at least the first 20 mm. Sectioning through the specimen reveals a 42 mm white spiculated mass which arises distal to the bifurcation of the left main bronchus. This appears to abut the hilar resection margin superior to the main bronchus. It is 2 mm from the pleural margin within the oblique fissure. The tumour macroscopically involves lymph nodes. There is purulent exudate distal to the tumour which obstructs large bronchi within the upper lobe. [Bronchial resection margin, 1A; peribronchial lymph nodes, 1B-1D; ? involved lymph node approaching pleura, 1E-1F; hilar soft tissue margin x 2, 1G; hilar soft tissue margin x 1, 1H-1J; representative section of tumour with left main bronchus, 1K; purulent exudate distal to obstruction, 1L; normal lung away from tumour, 1M].

2: The specimen is labelled 'No. 5 node' and consists of a fragment of adipose and nodal tissue measuring 13 x 12 x 8 mm. [Bisected and BIT, 2A].

MICROSCOPY

1: Sections show a poorly differentiated squamous cell carcinoma with extensive central necrosis. The tumour has a small endobronchial component as well as a parenchymal component. No lymphatic, vascular, perineural or pleural invasion is identified. However extensively necrotic metastatic carcinoma is present in at least one peribronchial lymph node. Tumour invades into hilar fat but is just clear of the soft tissue resection margin. Parenchyma distal to the tumour shows bronchiectasis and focal lipid pneumonia. There is also mild emphysema.

2: Sections show fragments of reactive lymphoid tissue in which there is no evidence of metastatic carcinoma.

SUMMARY

Left pneumonectomy and no. 5 lymph node:
Poorly differentiated squamous cell carcinoma, 42 mm in diameter.
No vascular, lymphatic, pleural or perineural invasion identified.
Invasion of hilar fat present.
Metastasis in peribronchial lymph node.
Pathological stage T3 N1.

A
N
A
T
O
M
I
C
A
L

P
A
T
H
O
L
O
G
Y

[page 2 of 2]
Histopathology Report

cc: Lung Cancer Registry

A
N
A
T
O
M
I
C
A
L

P
A
T
H
O
L
O

Source: NCI Genomic Data Commons file 938e18dd-09e7-4da0-a65f-9d84da2c8389 (TCGA-77-8148.2CCEF95D-EC8E-4B8D-987B-B7BF8AB2AA99.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).